Gene-level copy-number profile of tumor specimen C3N-00559-01 from CPTAC case C3N-00559, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 55.7 years (20,344 days).
Specimen C3N-00559-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0bfd96cf-a0e5-4cff-8b00-010c1a963074.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00559-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/c2afbf84-7168-4c7d-80e2-3f281e1e0f6f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 3,287; copy number 2: 22,675; copy number 3: 13,215; copy number 4: 16,176; copy number 5: 2,251; copy number 6: 425; copy number 7: 115; copy number 8: 77; copy number 9: 14; copy number 10: 37; copy number 11: 19; copy number 12: 3; copy number 13: 10; copy number 15: 17; copy number 16: 42; copy number 17: 2; copy number 18: 24; copy number 19: 1; copy number 24: 3.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr9:64,765,054–64,765,535, 1 gene: IGKV1OR-2.
- chr11:4,278,705–4,279,192, 1 gene: SSU72P6.
- chr11:55,602,360–55,652,854, 3 genes: OR4C11, OR4P4, OR4S2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,040 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,765,478–54,420,860, 24 genes, copy number 5: NDC1, AL049745.1, AL049745.2, YIPF1, DIO1, HSPB11, LRRC42, HNRNPA3P12, LDLRAD1, TMEM59, AL353898.3, TCEANC2, MIR4781, AL353898.1, AL353898.2, AL357673.1, CDCP2, AL357673.2, CYB5RL, MRPL37, SSBP3, SSBP3-AS1, AL161644.1, AL035415.1.
- chr6:13,825,432–13,826,574, 1 gene, copy number 9: AL023583.1.
- chr6:17,582,034–22,654,455, 51 genes, copy number 5 (within-gene range 4–5): SUMO2P13, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P, DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL008627.1, MBOAT1, AL158198.1, AL158198.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1.
- chr6:22,133,205–22,147,193, 1 gene, copy number 5 (within-gene range 4–5): NBAT1.
- chr6:23,337,711–24,719,998, 21 genes, copy number 5: AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2, ACOT13, AL031775.1, C6orf62, AL031775.2.
- chr6:41,247,369–42,452,051, 43 genes, copy number 5: TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1.
- chr6:43,427,366–44,450,425, 45 genes, copy number 5: ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642.
- chr7:37,032–11,169,623, 222 genes, copy number 5 (broad region; genes not listed).
- chr7:18,000,290–36,841,373, 339 genes, copy number 6 (broad region; genes not listed).
- chr7:42,954,135–65,814,775, 451 genes, copy number 5–16 (broad region; genes not listed).
- chr7:71,779,491–72,447,151, 1 gene, copy number 6 (within-gene range 4–6): CALN1.
- chr7:72,103,181–74,122,525, 64 genes, copy number 5–6 (broad region; genes not listed).
- chr8:41,929,479–43,378,510, 48 genes, copy number 5: KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3.
- chr8:78,675,743–78,805,523, 1 gene, copy number 5 (within-gene range 4–5): IL7.
- chr8:78,760,142–145,066,685, 1,026 genes, copy number 5 (broad region; genes not listed).
- chr12:50,756,892–50,940,026, 9 genes, copy number 8: AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA.
- chr12:52,543,909–53,054,450, 30 genes, copy number 7 (within-gene range 3–7): KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1, KRT77, AC055716.3, KRT126P, KRT125P, AC055716.2, AC055716.1, BTBD10P1, KRT127P, ARL2BPP2, KRT76, AC107016.2, KRT3, KRT4, KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1.
- chr12:54,549,601–54,896,008, 8 genes, copy number 7: PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1, VDAC1P5, MUCL1.
- chr12:57,738,013–58,395,138, 28 genes, copy number 7–15 (within-gene range 3–15): TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:59,596,029–59,789,855, 2 genes, copy number 17: SLC16A7, AC079905.2.
- chr12:67,929,235–68,971,570, 35 genes, copy number 7: LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:73,820,315–74,402,600, 1 gene, copy number 18 (within-gene range 3–18): LINC02882.
- chr12:74,039,024–74,293,096, 5 genes, copy number 18: LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3.
- chr12:74,728,038–74,728,851, 1 gene, copy number 19: AC123904.3.
- chr12:75,964,440–76,559,809, 14 genes, copy number 5 (within-gene range 3–5): AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8.
- chr12:80,068,691–81,759,553, 20 genes, copy number 5–13 (within-gene range 4–13): RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1.
- chr12:82,223,681–82,515,817, 6 genes, copy number 5–7: CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1.
- chr12:89,319,364–92,531,324, 54 genes, copy number 10–24: MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399, AC126178.1, LINC02392, LINC02822, AC084365.1, AC112481.2, AC112481.1, CCER1, LINC00615, EPYC, KERA, LUM, DCN, AC007115.1, LINC02823, AC126175.1, AC126175.2, AC025254.1, AC090049.2, LINC02404, AC090049.1, LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA, LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1.
- chr12:92,770,637–92,952,745, 4 genes, copy number 10–12 (within-gene range 3–12): EEA1, AC026111.1, HNRNPA1P50, RNU6-1329P.
- chr12:93,677,375–94,009,047, 7 genes, copy number 7: CRADD, AC012085.2, RN7SL630P, AC012464.2, AC012464.1, AC012464.3, RN7SKP263.
- chr16:25,691,959–32,436,203, 351 genes, copy number 5 (broad region; genes not listed).
- chr16:33,769,421–35,756,515, 104 genes, copy number 5 (broad region; genes not listed).
- chr19:34,849,046–35,154,302, 23 genes, copy number 5–10 (within-gene range 2–10): AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1, ZNF30, AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN, HPN-AS1, AC020907.1, AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1, AC020907.2, FXYD7.

Autosomal genes at a single copy (total copy number 1): 3,287. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
